Somatic mutation profile of tumor specimen TARGET-10-PAPAGW-09A (aliquot TARGET-10-PAPAGW-09A-01D) from TARGET case TARGET-10-PAPAGW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,586 days).
Specimen TARGET-10-PAPAGW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 494080e5-19f6-4788-b749-7251bef6bd3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAGW-14A (Bone Marrow Normal), aliquot TARGET-10-PAPAGW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cae02510-a621-4fc1-bbd1-69fd6e3ec7ab

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 2, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC1A | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1569356550, COSV59131454; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CPNE8 | c.697G>T p.V233L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100504404; called by mutect2, varscan2
- ADGRB1 | c.3917C>A p.S1306* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | called by muse, varscan2
- ALOX12B | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.101); called by mutect2, varscan2
- APH1B | c.599C>A p.S200* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- COL27A1 | c.2651C>A p.A884E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- GFY | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); called by muse, mutect2
- LRRN3 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR7G2 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2
- RBM33 | c.281C>A p.T94K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- HTR2C | c.1206C>A p.A402= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV52208035; called by muse, mutect2
- FABP3 | c.*9C>T | 3'UTR (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
